FM case AD2970 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Transitional Cell Papillomas and Carcinomas; Primary site: Ureter.
https://portal.gdc.cancer.gov/cases/7d5fa7b4-f594-4868-b746-3e6edf709592

Female, 52.6 years: Urothelial carcinoma, NOS (ICD-O-3 8120/3) of the ureter; metastasis biopsied or resected from the lymph node. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Metastatic.
